Gene-level copy-number profile of specimen HCM-CSHL-0810-C54-85B from HCMI case HCM-CSHL-0810-C54, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Uterus, NOS; AJCC pathologic stage: Stage IIIC.
Specimen HCM-CSHL-0810-C54-85B: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 15.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 61f48774-5a03-4e81-8999-1b771a4724e9.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-CSHL-0810-C54-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,233 have no estimate.
https://portal.gdc.cancer.gov/files/a663fb3b-c4ea-49f0-83ad-47f79edc600d

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 103; copy number 2: 13,086; copy number 3: 30,622; copy number 4: 12,482; copy number 5: 1,608; copy number 6: 302; copy number 7: 64; copy number 8: 95; copy number 9: 12; copy number 12: 16.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 187 genes in 12 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:75,835,663–75,888,926, 2 genes, copy number 8: AC005102.1, RHBDD2.
- chr7:149,033,057–149,297,312, 12 genes, copy number 9: RNU6-650P, COX6B1P1, ZNF786, ZNF425, RN7SL521P, ZNF398, AC004890.1, ZNF282, ZNF212, ZNF783, AC004890.3, AC004890.2.
- chr8:41,645,177–43,674,591, 65 genes, copy number 7–12 (broad region; genes not listed).
- chr12:55,900,300–56,449,426, 49 genes, copy number 8: GSTP1P1, PYM1, DGKA, AC025162.2, PMEL, CDK2, AC025162.1, RAB5B, AC034102.1, SUOX, IKZF4, AC034102.8, AC034102.3, RPS26, ERBB3, AC034102.2, PA2G4, AC034102.4, RPL41, ESYT1, ZC3H10, AC034102.7, AC034102.6, AC034102.5, MYL6B, MYL6, SMARCC2, AC073896.4, RNF41, NABP2, SLC39A5, ANKRD52, COQ10A, AC073896.5, CS, AC073896.1, AC073896.2, AC073896.3, CNPY2, PAN2, IL23A, STAT2, RNU7-40P, APOF, APONP, AC025574.1, AC024884.2, AC024884.1, TIMELESS.
- chr14:103,207,748–103,374,916, 10 genes, copy number 8: AL161669.2, AL161669.3, RPL21P13, RAP2CP1, AL138976.1, AL138976.2, EIF5, SNORA28, HMGB3P26, RPSAP5.
- chr17:39,057,019–39,564,907, 14 genes, copy number 8 (within-gene range 6–8): RDM1P5, PLXDC1, AC091178.2, ARL5C, AC004408.2, AC004408.1, CACNB1, RPL19, STAC2, AC015910.1, FBXL20, AC005288.1, MED1, CDK12.
- chr19:23,015,059–23,031,818, 1 gene, copy number 7: LINC01859.
- chr19:23,596,122–23,598,159, 2 genes, copy number 7 (within-gene range 6–7): AC073544.1, RPS27P29.
- chr19:44,905,791–44,931,386, 4 genes, copy number 7: APOE, AC011481.3, APOC1, APOC1P1.
- chr19:47,332,175–47,382,704, 2 genes, copy number 7: C5AR2, DHX34.
- chr20:48,624,252–49,484,297, 20 genes, copy number 8: PREX1, AL035106.1, AL133342.1, ARFGEF2, SNAP23P1, CSE1L-AS1, CSE1L, STAU1, ARPC3P1, DDX27, ZNFX1, ZFAS1, AL049766.2, SNORD12C, AL049766.1, SNORD12B, AL049766.3, SNORD12, KCNB1, AL035685.1.
- chr22:24,657,481–24,774,720, 6 genes, copy number 7: POM121L10P, ARL5AP4, AP000357.1, AP000358.1, CRIP1P4, PIWIL3.

Autosomal genes at a single copy (total copy number 1): 103. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
